Somatic mutation profile of tumor specimen 0DB130 from CCDI case PBBKJI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,766 days).
Specimen 0DB130: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66befeff-4927-4a36-a5f0-a154b7bb4597.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB131 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97809761-6e21-4713-ac74-6ef2dda1fa93

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMX | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751155900, COSV59590556; called by muse, mutect2, varscan2
- PADI4 | c.1736C>A p.A579E | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERPINA11 | c.558G>A p.R186= | Silent (SNP) | VAF 46/214 reads (21%) | called by muse, mutect2, varscan2
- ZDHHC15 | c.825A>G p.G275= | Silent (SNP) | VAF 81/349 reads (23%) | called by muse, mutect2, varscan2
- TMEM185B | c.*3648C>T | 3'UTR (SNP) | VAF 46/232 reads (20%) | catalogued as rs544345765; called by muse, mutect2
